Gene-level copy-number profile of tumor specimen TCGA-G5-6641-01A from TCGA case TCGA-G5-6641, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.0 years (24,486 days).
Specimen TCGA-G5-6641-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.af2cffcf-a277-425a-9ebb-246b51fd1cb2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G5-6641-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3019fb5c-66ba-48bf-b2d8-54d94d94cb8e

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 230; copy number 3: 6,133; copy number 4: 9,400; copy number 5: 25,839; copy number 6: 8,282; copy number 7: 5,357; copy number 8: 2,806; copy number 9: 1,355; copy number 11: 10; copy number 13: 54; copy number 14: 8; copy number 16: 101; copy number 18: 29; copy number 19: 31; copy number 23: 75; copy number 31: 52; copy number 37: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G5-6641-01A-11D-1825-01): tumor purity 0.77, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 412 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–5,521,536, 136 genes, copy number 11–31 (broad region; genes not listed).
- chr12:5,583,797–5,584,085, 1 gene, copy number 11: AC137627.1.
- chr12:18,683,169–18,738,100, 1 gene, copy number 16 (within-gene range 3–16): PLCZ1.
- chr12:18,714,795–19,724,599, 16 genes, copy number 16: AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P.
- chr12:20,368,537–20,688,583, 1 gene, copy number 18 (within-gene range 5–18): PDE3A.
- chr12:20,551,590–21,419,594, 10 genes, copy number 18 (within-gene range 4–18): AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP.
- chr12:22,008,348–29,784,759, 133 genes, copy number 14–37 (within-gene range 8–37) (broad region; genes not listed).
- chr12:33,374,238–34,249,958, 18 genes, copy number 18: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr12:67,978,107–72,728,844, 96 genes, copy number 13–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
